Gene-level copy-number profile of tumor specimen TCGA-RD-A8N9-01A from TCGA case TCGA-RD-A8N9, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 63.1 years (23,059 days).
Specimen TCGA-RD-A8N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.fc8d46a7-5cd1-4cf6-a170-390af6b91575.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A8N9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4a2da207-d11a-4320-a583-34e9c949532c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 5,736; copy number 2: 24,912; copy number 3: 23,123; copy number 4: 4,394; copy number 5: 709; copy number 6: 573; copy number 7: 346; copy number 9: 3; copy number 10: 1; copy number 22: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A8N9-01A-12D-A396-01): tumor purity 0.37, ploidy 2.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,582,221–58,863,414, 4 genes (within-gene range 0–2): RAB3C, AC016642.1, RPL5P15, AC008852.1.
- chr5:59,039,761–59,314,800, 2 genes: AC092343.1, AC008833.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,641 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:27,217,714–45,895,970, 285 genes, copy number 7 (broad region; genes not listed).
- chr8:5,072,645–18,084,998, 362 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:135,457,456–145,066,685, 228 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:37,322,259–38,424,454, 30 genes, copy number 5–7: Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5, AL138752.2, RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3, DCAF10, AL138752.1, PAICSP1, SLC25A51, TMX2P1, SHB, RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1.
- chr9:38,452,782–38,479,350, 2 genes, copy number 5 (within-gene range 3–5): ARMC8P1, TCEA1P3.
- chr11:74,397,549–74,485,742, 3 genes, copy number 9 (within-gene range 3–9): AP001372.1, AP001085.1, MIR548AL.
- chr12:124,206,228–127,636,488, 82 genes, copy number 6 (broad region; genes not listed).
- chr13:75,871,038–84,448,603, 88 genes, copy number 6 (broad region; genes not listed).
- chr13:96,090,839–98,752,672, 39 genes, copy number 7: HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1.
- chr14:22,011,910–22,490,553, 55 genes, copy number 5 (within-gene range 3–5): AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr18:47,390–23,026,488, 426 genes, copy number 5–22 (broad region; genes not listed).
- chr20:58,097,267–59,397,109, 41 genes, copy number 6: AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1.

Autosomal genes at a single copy (total copy number 1): 5,736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
